Somatic mutation profile of tumor specimen TCGA-EJ-8470-01A (aliquot TCGA-EJ-8470-01A-11D-2395-08) from TCGA case TCGA-EJ-8470, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.1 years (21,209 days).
Specimen TCGA-EJ-8470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 898a24ce-da0e-4e40-afa0-d011f6050cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-8470-10A (Blood Derived Normal), aliquot TCGA-EJ-8470-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6e733f5-2323-42ac-acaf-90867393ca58

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMIGO2 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 34/184 reads (18%) | catalogued as COSV56973550; called by muse, mutect2, varscan2
- BTBD10 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV53397973; called by muse, mutect2, varscan2
- DBH | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs770756255, COSV55040017; called by muse, mutect2, varscan2
- DNAH1 | c.8687A>G p.N2896S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as rs749810861, COSV70227146; called by muse, mutect2, varscan2
- DNAH3 | c.11608G>T p.E3870* | Nonsense Mutation (SNP) | VAF 154/650 reads (24%) | catalogued as COSV54509512; called by muse, mutect2, varscan2
- FKBP15 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53032730; called by muse, mutect2, varscan2
- FOXP2 | c.1542G>C p.R514S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63483224; called by muse, mutect2, varscan2
- GNA13 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV71474487; called by muse, mutect2, varscan2
- NFE2L1 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62582896; called by muse, mutect2, varscan2
- PCDHB6 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 35/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50691548; called by muse, mutect2
- PDCD5 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55678094; called by muse, mutect2, varscan2
- PRAMEF19 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 25/332 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.476); catalogued as rs1274389350; called by muse, mutect2, varscan2
- RAPH1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as rs769654955, COSV55582203; called by muse, mutect2, varscan2
- SLC1A6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs996260256, COSV55667680; called by muse, mutect2, varscan2
- ZNF165 | c.1429A>C p.I477L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV66102099; called by muse, mutect2, varscan2
- FLT1 | c.2332del p.L778Sfs*6 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- ANKS3 | c.141G>A p.Q47= | Silent (SNP) | VAF 47/451 reads (10%) | catalogued as rs148767427; called by muse, mutect2, varscan2
- SLC25A28 | c.450C>T p.A150= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs1458666231, COSV65125206; called by muse, mutect2, varscan2
- UTP23 | c.615T>A p.L205= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV59123949; called by muse, mutect2, varscan2
